Somatic mutation profile of tumor specimen 5c9ee07a-ca8f-49bf-9c03-2dc513 (aliquot 5c9ee07a-ca8f-49bf-9c03-2dc513_D6_2) from CPTAC case 18BR009, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.5 years (23,177 days).
Specimen 5c9ee07a-ca8f-49bf-9c03-2dc513: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2199ff9-40c2-4311-91a7-e8406d1bc5e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a4e97f71-27e2-44ed-9f3a-76a987 (Blood Derived Normal), aliquot a4e97f71-27e2-44ed-9f3a-76a987_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b525613-1e2b-4aba-a3cf-df2dbc17ea15

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Splice Region 2, Nonsense Mutation 2, In Frame Del 1, 5'UTR 1, 3'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 42/624 reads (7%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2
- ARHGEF10 | c.1515G>A p.S505= (on ENST00000398564; = p.S480= on NM_014629.4) | Splice Region (SNP) | VAF 18/250 reads (7%) | catalogued as rs1201139669, COSV50648933; called by muse, mutect2
- ARHGEF17 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV55231616; called by muse, mutect2
- CABLES2 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs765990633; called by muse, mutect2
- EPN3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752524025, COSV99277211; called by muse, mutect2
- MBL2 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64758917; called by muse, mutect2
- NTRK2 | c.1768G>T p.E590* (on ENST00000323115 / NM_001369534.1; = p.E606* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/260 reads (3%) | catalogued as COSV52879250; called by muse, mutect2
- RGS9 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1297046332, COSV99287738; called by muse, mutect2
- TNC | c.2200C>T p.P734S | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs751036493; called by muse, mutect2
- ZNF862 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV56226575; called by muse, mutect2
- AFMID | c.905T>C p.F302S | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BCS1L | c.411C>A p.F137L | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CRB1 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EPC2 | c.2016A>G p.S672= | Splice Region (SNP) | VAF 10/104 reads (10%) | called by muse, mutect2
- GPR61 | c.693G>A p.M231I | Missense Mutation (SNP) | VAF 14/401 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.047); called by muse, mutect2
- KAT7 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- KCNQ5 | c.1308G>C p.K436N | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- KDR | c.2704C>G p.L902V | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MORC1 | c.1128G>C p.L376F | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MRC2 | c.521A>G p.E174G | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); called by muse, mutect2
- NCKAP5 | c.1910_1912del p.Q637_V638delinsL | In Frame Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- OR4K17 | c.824A>T p.Y275F | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); called by muse, mutect2
- OR5P3 | c.638T>C p.V213A | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2
- PHLDB2 | c.3322C>T p.P1108S (on ENST00000393925 / NM_001134439.2; = p.P1065S on NM_145753.2) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PRPF19 | c.1235A>C p.D412A | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SEZ6L2 | c.1713-1G>C p.X571_splice (on ENST00000308713 / NM_001114099.3; = p.X501_splice on NM_012410.4) | Splice Site (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- SI | c.1164T>G p.D388E | Missense Mutation (SNP) | VAF 38/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC24A5 | c.830A>C p.Q277P | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.335); called by muse, mutect2
- SPAG9 | c.3094C>A p.Q1032K (on ENST00000262013 / NM_001130528.3; = p.Q1018K on NM_003971.6) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- TLN2 | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2
- TRPM2 | c.3867G>A p.M1289I | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- ZNF106 | c.4111G>A p.D1371N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AFMID | c.906C>T p.F302= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs200823680; called by muse, mutect2
- BICRAL | c.1296C>T p.L432= | Silent (SNP) | VAF 14/314 reads (4%) | called by muse, mutect2
- CHD5 | c.3939G>A p.E1313= | Silent (SNP) | VAF 19/235 reads (8%) | catalogued as rs750701843; called by muse, mutect2
- ELMO3 | c.594C>T p.L198= (on ENST00000652269; = p.L145= on NM_024712.5) | Silent (SNP) | VAF 21/273 reads (8%) | catalogued as rs775151130; called by muse, mutect2
- OR5C1 | c.267G>C p.L89= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- PILRA | c.282G>A p.V94= | Silent (SNP) | VAF 42/556 reads (8%) | catalogued as COSV104388762; called by muse, mutect2
- PTGER2 | c.165G>A p.G55= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs753177423, COSV99817245; called by muse, mutect2
- TGFA | c.378C>G p.V126= | Silent (SNP) | VAF 5/133 reads (4%) | called by muse, mutect2
- TTLL3 | c.279C>A p.L93= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs560428064, COSV55028109; called by muse, mutect2, varscan2
- UTP20 | c.3036G>A p.L1012= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- CICP28 | chr7:56812144 G>A | 3'Flank (SNP) | VAF 14/204 reads (7%) | catalogued as rs1554353694; called by muse, mutect2
- LINC02656 | n.215T>C | RNA (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- MOB1B | c.-62C>T | 5'UTR (SNP) | VAF 11/133 reads (8%) | catalogued as COSV58674933; called by muse, mutect2
